Somatic mutation profile of tumor specimen TCGA-61-1730-01A (aliquot TCGA-61-1730-01A-01W-0639-09) from TCGA case TCGA-61-1730, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 78.1 years (28,508 days).
Specimen TCGA-61-1730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf4a31ef-b830-4f1e-b3ae-70d79ba77e99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1730-11A (Solid Tissue Normal), aliquot TCGA-61-1730-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/783ca049-e36b-455d-8c64-cf2314978145

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 5, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 51/62 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.3227T>A p.I1076K | Missense Mutation (SNP) | VAF 72/1238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1356591712, COSV99684907; called by muse, mutect2
- ABCC9 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 58/1080 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs200349671, CM141606; ClinVar: uncertain significance; called by muse, mutect2
- AGO3 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.066); catalogued as COSV55793780; called by muse, mutect2, varscan2
- ALK | c.4753G>A p.G1585S | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66570550; called by muse, mutect2, varscan2
- AMY2B | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 65/235 reads (28%) | catalogued as rs770249517, COSV63714026; called by muse, mutect2, varscan2
- ANKRD35 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs782048147, COSV62910517; called by muse, mutect2, varscan2
- ASIC1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs1383168382, COSV57318221; called by muse, mutect2
- ATRN | c.2854T>G p.C952G | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53528526; called by muse, mutect2, varscan2
- ATXN2 | c.2827C>A p.Q943K (on ENST00000550104; = p.Q783K on NM_002973.4) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV101112630; called by muse, mutect2
- C15orf39 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); catalogued as COSV100641231; called by muse, mutect2, varscan2
- C9 | c.1529G>T p.C510F | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54674368, COSV54677344; called by muse, mutect2, varscan2
- CABP5 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.309); catalogued as COSV53152869; called by muse, mutect2, varscan2
- CDH4 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV64656836; called by muse, mutect2, varscan2
- CFAP58 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100458802; called by muse, mutect2
- CHMP1B | c.561A>T p.E187D | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV99303200; called by muse, mutect2
- CTAGE6 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759852922, COSV101417822, COSV101417858; called by muse, mutect2
- ELOA | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.77); catalogued as COSV101403638; called by muse, mutect2
- ELOVL3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV64174541; called by muse, mutect2, varscan2
- EP400 | c.4201C>T p.R1401W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs201961439; called by muse, mutect2, varscan2
- FAT1 | c.9400G>T p.V3134L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs777328292, COSV71674424; called by muse, mutect2, varscan2
- FGFR2 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100335534; called by muse, mutect2
- FLG2 | c.4892C>G p.S1631C | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV101165669; called by muse, mutect2
- FLG2 | c.4891T>G p.S1631A | Missense Mutation (SNP) | VAF 24/565 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101165670; called by muse, mutect2
- GOLGA1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 441/508 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV65221255; called by muse, mutect2, varscan2
- GPA33 | c.524G>T p.W175L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100900954; called by muse, mutect2
- ITGA6 | c.2464G>T p.A822S (on ENST00000442250; = p.A783S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.393); catalogued as COSV51227311; called by muse, mutect2, varscan2
- KIF1B | c.2026C>G p.Q676E (on ENST00000377086 / NM_001365952.1; = p.Q630E on NM_015074.3) | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.53); catalogued as COSV55809577; called by muse, mutect2, varscan2
- MACF1 | c.20598C>A p.H6866Q (on ENST00000372915; = p.H4911Q on NM_012090.5) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV57124306; called by muse, mutect2, varscan2
- MC5R | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100228964; called by muse, mutect2
- MMP9 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs1291812181, COSV63434152; called by muse, mutect2, varscan2
- MYH8 | c.2072T>C p.L691P | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV101238302; called by muse, mutect2
- NIFK | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV99590585; called by muse, mutect2
- NMD3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV63618686; called by muse, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- NRROS | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV60746236; called by muse, mutect2, varscan2
- OR8K5 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2, varscan2
- PARD3B | c.3608C>A p.A1203E (on ENST00000406610 / NM_001302769.2; = p.A1134E on NM_057177.7) | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100592566; called by muse, mutect2
- PLCG1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs764899653, COSV54819300; called by muse, mutect2, varscan2
- PLD1 | c.699C>A p.H233Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100577770; called by muse, mutect2
- PTDSS2 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57278429; called by muse, mutect2, varscan2
- PXDC1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV66661629, COSV66661669; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1214A>T p.D405V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs1259081793, COSV99920775; called by muse, mutect2
- RIPOR1 | c.162dup p.A55Rfs*67 (on ENST00000379312 / NM_001193522.2; = p.A51Rfs*67 on NM_024519.4) | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs763705850; called by pindel, varscan2
- RNF213 | c.8353G>A p.A2785T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758896947, COSV60399100; called by muse, mutect2, varscan2
- TAS2R41 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV101281477, COSV101281508; called by muse, mutect2
- THOC2 | c.1152C>G p.C384W | Missense Mutation (SNP) | VAF 139/166 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55547125; called by muse, mutect2, varscan2
- TNFRSF8 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as rs868408646, COSV55796948; called by muse, mutect2, varscan2
- VCAN | c.302T>A p.V101E | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54106555; called by muse, mutect2, varscan2
- WFIKKN2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs760268496, COSV60958949; called by muse, mutect2, varscan2
- ZNF17 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56921561; called by muse, mutect2, varscan2
- KDM5C | c.2737del p.V913Wfs*22 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | called by mutect2, varscan2
- KPNA6 | c.1551_1552del p.E517Dfs*11 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel*, varscan2*
- MFSD4A | c.1417_1420dup p.G474Vfs*38 | Frame Shift Ins (INS) | VAF 95/197 reads (48%) | called by mutect2, pindel, varscan2
- MRC1 | c.3107G>T p.G1036V | Missense Mutation (SNP) | VAF 420/573 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC30A5 | c.2024_2026del p.S675del | In Frame Del (DEL) | VAF 40/124 reads (32%) | called by mutect2, pindel, varscan2
- VPS13A | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2
- AFDN | c.4521G>A p.S1507= | Silent (SNP) | VAF 4/100 reads (4%) | catalogued as rs963086126, COSV60054259; called by muse, mutect2
- AHNAK2 | c.2961C>T p.A987= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs371134105, COSV60917130; called by muse, mutect2, varscan2
- CLK4 | c.150A>G p.K50= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV60318996; called by muse, mutect2, varscan2
- CNBD2 | c.1563G>A p.K521= (on ENST00000373973 / NM_001365709.1; = p.K517= on NM_080834.4) | Silent (SNP) | VAF 89/411 reads (22%) | catalogued as COSV62587064; called by muse, mutect2, varscan2
- DCK | c.495A>G p.Q165= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs576990251, COSV54378669; called by muse, mutect2, varscan2
- DGKD | c.261G>T p.T87= (on ENST00000264057 / NM_152879.3; = p.T43= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as COSV51051624; called by muse, mutect2, varscan2
- FAM81A | c.219C>T p.R73= | Silent (SNP) | VAF 57/255 reads (22%) | catalogued as rs1235439009, COSV55677976; called by muse, mutect2, varscan2
- KRT6A | c.405C>T p.I135= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV100416805; called by muse, mutect2, varscan2
- LMBRD2 | c.858C>T p.N286= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV56950503; called by muse, mutect2, varscan2
- MMP3 | c.1105C>A p.R369= | Silent (SNP) | VAF 6/133 reads (5%) | catalogued as COSV55406874; called by muse, mutect2
- PMS2 | c.2301G>C p.L767= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99763986; called by muse, mutect2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- TDRKH | c.114G>A p.R38= | Silent (SNP) | VAF 63/152 reads (41%) | catalogued as COSV64316367; called by muse, mutect2, varscan2
- TULP3 | c.1191T>C p.N397= | Silent (SNP) | VAF 399/439 reads (91%) | catalogued as COSV68118012; called by muse, mutect2, varscan2
- GP6 | c.*502C>T | 3'UTR (SNP) | VAF 54/245 reads (22%) | catalogued as rs778801507, COSV59977773; called by muse, mutect2, varscan2
- MDS2 | n.525C>T | RNA (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
